Somatic mutation profile of tumor specimen ASCProject_0221_T1_WES (aliquot ASCProject_0221_T1_WES_1) from CMI case ASCProject_0221, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 27.1 years (9,905 days).
Specimen ASCProject_0221_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650cd50d-2ddc-4713-9505-a2bfc398de67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0221_SALIVA (Saliva), aliquot ASCProject_0221_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/291f5855-6e85-43df-b0a5-40313cf1ba24

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Frame Shift Del 4, Silent 4, RNA 2, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3362C>T p.S1121L | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs63750987, CM014488, CM053089; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 60/427 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53091312; called by muse, mutect2, varscan2
- ABCA3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs746682954; called by muse, mutect2, varscan2
- BOK | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs748812814; called by muse, mutect2, varscan2
- EPDR1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs369217258; called by muse, mutect2, varscan2
- FGF21 | c.392del p.G131Dfs*64 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | catalogued as COSV55809865; called by mutect2, pindel, varscan2
- FNTA | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 37/172 reads (22%) | catalogued as rs767603793, COSV56491327; called by muse, mutect2, varscan2
- OR10A5 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55055229; called by muse, mutect2, varscan2
- SLC9B1 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs1171151766; called by muse, mutect2, varscan2
- SRGAP2 | c.1210del p.E404Rfs*27 (on ENST00000624873 / NM_001170637.4; = p.E405Rfs*27 on NM_015326.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/338 reads (17%) | catalogued as COSV99832810; called by mutect2, pindel, varscan2
- UGT3A2 | c.452del p.P151Lfs*3 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as COSV56928229; called by mutect2, pindel, varscan2
- ADAMTS2 | c.3016G>T p.D1006Y | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ARID1A | c.5418del p.S1807Vfs*8 | Frame Shift Del (DEL) | VAF 59/241 reads (24%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- EPHB4 | c.2400dup p.S801Qfs*2 | Frame Shift Ins (INS) | VAF 81/237 reads (34%) | called by mutect2, pindel, varscan2
- FBN3 | c.5719G>T p.A1907S | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.415); called by muse, mutect2
- LRP2 | c.1564G>A p.G522S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSC-AS1 | n.438T>G | Splice Region (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2, varscan2
- NRAS | c.349A>C p.K117Q | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PIK3CA | c.2869A>C p.T957P | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); called by muse, varscan2
- PLCH1 | c.2690G>C p.R897T (on ENST00000340059 / NM_001130960.2; = p.R889T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- POT1 | c.221A>T p.K74I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTDSS1 | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- TAC1 | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2
- TENM1 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- TMX4 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, varscan2
- TP53BP1 | c.3968C>T p.A1323V | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.94); called by muse, mutect2
- ZBTB18 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AHNAK2 | c.11886G>T p.T3962= | Silent (SNP) | VAF 43/490 reads (9%) | catalogued as rs371817706, COSV60908996; called by muse, mutect2, varscan2
- ISLR | c.223C>T p.L75= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV99997428; called by muse, mutect2, varscan2
- MECOM | c.738G>C p.A246= (on ENST00000468789 / NM_001105078.4; = p.A434= on NM_004991.4) | Silent (SNP) | VAF 59/169 reads (35%) | catalogued as COSV52960807; called by muse, mutect2, varscan2
- TARM1 | c.261G>A p.A87= (on ENST00000616041 / NM_001330650.1; = p.A79= on NM_001135686.3) | Silent (SNP) | VAF 82/342 reads (24%) | catalogued as rs760187546; called by muse, mutect2, varscan2
- HAVCR1 | c.*28C>T | 3'UTR (SNP) | VAF 32/104 reads (31%) | catalogued as rs1177354352, COSV100208308; called by muse, mutect2, varscan2
- LINC01193 | n.780T>C | RNA (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- MIR125B1 | n.84G>C | RNA (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
